Somatic mutation profile of tumor specimen TCGA-MA-AA41-01A (aliquot TCGA-MA-AA41-01A-11D-A387-09) from TCGA case TCGA-MA-AA41, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 33.9 years (12,398 days).
Specimen TCGA-MA-AA41-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 982eaae0-ca19-49d3-8bf0-71e8c097e78d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MA-AA41-10A (Blood Derived Normal), aliquot TCGA-MA-AA41-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40980ee1-de5c-4394-ad0c-bce98be87780

The open-access MAF lists 534 somatic variants for this specimen: 383 protein-altering or splice-affecting, 134 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 333, Silent 134, Nonsense Mutation 36, Intron 7, RNA 5, Splice Region 5, Splice Site 5, 3'UTR 3, Frame Shift Del 3, In Frame Del 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SI | c.3370C>T p.R1124* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as rs200451408, CM1210571; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62930727; called by muse, mutect2, varscan2
- AAGAB | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99971760; called by muse, mutect2, varscan2
- ABCA3 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as COSV100067992; called by muse, mutect2, varscan2
- AC098582.1 | c.2854C>T p.P952S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.645); catalogued as rs1223642403, COSV99985283; called by muse, mutect2, varscan2
- ACP3 | c.185C>G p.S62* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV60489542; called by muse, mutect2, varscan2
- ACTL9 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1420072536, COSV61005519; called by muse, mutect2, varscan2
- ADAMTS1 | c.2397G>C p.L799F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV99535854; called by muse, mutect2, varscan2
- ADCY2 | c.2076G>A p.M692I | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs555132618, COSV100601785; called by muse, mutect2, varscan2
- ADD1 | c.2174C>T p.P725L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1325197018, COSV53268356; called by muse, mutect2, varscan2
- ADGRL1 | c.3439-1G>A p.X1147_splice (on ENST00000340736 / NM_001008701.3; = p.X1142_splice on NM_014921.5) | Splice Site (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100529253; called by muse, mutect2
- AGMO | c.1128G>C p.L376F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as rs998380106, COSV61106351, COSV61112706; called by muse, mutect2, varscan2
- AGTR1 | c.309T>G p.I103M | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.403); catalogued as COSV100836927; called by muse, mutect2, varscan2
- AHNAK2 | c.14556G>C p.M4852I | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV100315550; called by muse, mutect2, varscan2
- AKAP4 | c.1790C>T p.S597L | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100654143; called by muse, mutect2, varscan2
- ALG10B | c.1164G>C p.L388F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); catalogued as COSV100439787; called by muse, mutect2, varscan2
- ALG14 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV100930816; called by muse, mutect2, varscan2
- ALK | c.2437G>C p.E813Q | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV101201193; called by muse, mutect2, varscan2
- AMER1 | c.3176G>A p.S1059N | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100365282; called by muse, mutect2, varscan2
- AMHR2 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV57685390, COSV99142993; called by muse, mutect2, varscan2
- AMPD3 | c.2173G>C p.E725Q (on ENST00000396553 / NM_001025389.2; = p.E734Q on NM_000480.3) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV101158081; called by muse, mutect2, varscan2
- ANK3 | c.7570G>C p.E2524Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV99778287; called by muse, mutect2, varscan2
- ANKRD12 | c.2764C>G p.L922V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs749333227, COSV100040718; called by mutect2, varscan2
- ANKS3 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as rs113252244, COSV100422903; called by muse, mutect2, varscan2
- ARAP2 | c.4870C>T p.R1624* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as rs868517624, COSV58282896; called by muse, mutect2
- ARL4A | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1436382457, COSV100775882; called by muse, mutect2, varscan2
- ARV1 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1237229089, COSV100048248; called by muse, mutect2, varscan2
- ASB8 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100402259; called by muse, mutect2, varscan2
- ASPM | c.9002G>C p.R3001T | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV99659501; called by muse, mutect2, varscan2
- ATAD2 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs761504959, COSV54882160; called by muse, mutect2, varscan2
- ATP10A | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63512963; called by muse, mutect2, varscan2
- ATP13A4 | c.3070C>T p.P1024S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV61321197; called by muse, mutect2, varscan2
- ATP1B3 | c.554G>C p.G185A | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99657131; called by muse, mutect2, varscan2
- ATP5F1A | c.1540C>T p.H514Y | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.031); catalogued as COSV99958726; called by muse, mutect2, varscan2
- ATXN3L | c.1035G>A p.M345I | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV101019312; called by muse, mutect2, varscan2
- B4GALT4 | c.252C>G p.L84= | Splice Region (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100785755; called by muse, mutect2, varscan2
- BAP1 | c.1379C>G p.S460* | Nonsense Mutation (SNP) | VAF 13/17 reads (76%) | catalogued as COSV56231488; called by muse, mutect2, varscan2
- BMP3 | c.69G>T p.E23D | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV99261367; called by muse, mutect2, varscan2
- BMT2 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99774399; called by muse, mutect2, varscan2
- BPIFA3 | c.194G>C p.R65T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.22); catalogued as COSV100966996; called by muse, mutect2, varscan2
- BRWD3 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as COSV100955647; called by muse, mutect2, varscan2
- BSG | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100344471; called by muse, mutect2, varscan2
- C1orf94 | c.1358C>T p.S453L (on ENST00000488417 / NM_001134734.2; = p.S263L on NM_032884.5) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs140823731; called by muse, mutect2
- C2CD2 | c.1542C>G p.I514M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100297989, COSV100298347; called by muse, mutect2, varscan2
- C2orf78 | c.591G>T p.Q197H | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV101280898; called by muse, mutect2
- C2orf78 | c.2022G>A p.W674* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as COSV101280899; called by muse, mutect2
- CACNA1E | c.6118G>C p.E2040Q (on ENST00000367573 / NM_001205293.3; = p.E1997Q on NM_000721.4) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100701281, COSV62381531; called by muse, mutect2, varscan2
- CAPN7 | c.2224G>C p.E742Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as COSV99508051; called by muse, mutect2, varscan2
- CARHSP1 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.652); catalogued as rs770141066, COSV60683427; called by muse, mutect2, varscan2
- CCDC121 | c.410C>G p.S137* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99269815; called by muse, mutect2, varscan2
- CCDC174 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as rs758812410, COSV100358417, COSV100358684; called by muse, mutect2, varscan2
- CD1A | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as COSV99192175; called by mutect2, varscan2
- CD33 | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as COSV51805235, COSV99220052; called by muse, mutect2, varscan2
- CDC42BPA | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100503727; called by muse, mutect2, varscan2
- CDC42EP4 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776312011, COSV100231735; called by mutect2, varscan2
- CDHR2 | c.3781C>T p.Q1261* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99991008, COSV99992161; called by muse, mutect2, varscan2
- CDK6 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV99720712; called by muse, mutect2, varscan2
- CDON | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99700597; called by muse, mutect2, varscan2
- CENPE | c.3780G>C p.E1260D | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99476981; called by muse, mutect2, varscan2
- CENPQ | c.207G>T p.K69N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.133); catalogued as COSV100225611; called by muse, varscan2
- CEP192 | c.5384C>A p.S1795Y | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs913283512, COSV100380569; called by muse, mutect2, varscan2
- CFAP54 | c.7936C>G p.Q2646E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as rs749029161, COSV100732940; called by muse, mutect2, varscan2
- CFHR5 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as COSV99887930; called by muse, mutect2, varscan2
- CHD1 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.376); catalogued as rs1433272156, COSV99399087; called by muse, mutect2
- CHD7 | c.6580G>A p.E2194K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV101417988; called by muse, mutect2, varscan2
- CHKB | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0.127); catalogued as COSV100376483; called by muse, mutect2, varscan2
- CILP | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.051); catalogued as rs1348624871, COSV99972773, COSV99973553; called by muse, mutect2, varscan2
- CLASP2 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV100222509; called by muse, mutect2, varscan2
- CLCN2 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99658213; called by muse, mutect2, varscan2
- CLDN1 | c.391C>G p.L131V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.759); catalogued as COSV99790480; called by muse, mutect2
- CLMP | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs867962634, COSV101507369; called by muse, mutect2, varscan2
- CLPTM1 | c.1137C>G p.I379M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100493596, COSV61611894; called by muse, mutect2, varscan2
- CLUL1 | c.375G>T p.M125I | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV100620905; called by muse, mutect2, varscan2
- CNTN3 | c.2939G>A p.G980E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99723241; called by muse, mutect2, varscan2
- CNTN5 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99672838; called by muse, mutect2, varscan2
- COL13A1 | c.603G>A p.P201= (on ENST00000398978 / NM_001130103.2; = p.P163= on NM_080798.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 12/65 reads (18%) | catalogued as rs754867905, COSV100637276, COSV62572697; called by muse, mutect2, varscan2
- COL1A1 | c.4201G>A p.E1401K | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs760860681, COSV56805466; called by muse, mutect2
- COL20A1 | c.3139G>A p.E1047K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as COSV100489902; called by muse, mutect2, varscan2
- COL4A2 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs568655744, COSV100847183; called by muse, mutect2, varscan2
- COL6A6 | c.1510G>C p.E504Q | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.522); catalogued as rs1472916651, COSV100649795; called by muse, mutect2
- CR1 | c.3799C>G p.H1267D | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.167); catalogued as COSV100887387; called by muse, mutect2, varscan2
- CRYBG3 | c.6946C>A p.P2316T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.383); catalogued as rs778114780, COSV99476600; called by muse, mutect2, varscan2
- CSNK1G1 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779009615, COSV57313912; called by muse, mutect2, varscan2
- CTC1 | c.2677G>A p.D893N | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as COSV100236136; called by muse, mutect2, varscan2
- CTC1 | c.2425G>C p.E809Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.474); catalogued as rs761824247, COSV100236138; called by muse, mutect2, varscan2
- CUBN | c.3745C>T p.R1249C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs368224687; called by muse, mutect2, varscan2
- CUL9 | c.5773G>A p.D1925N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV99334755; called by muse, mutect2, varscan2
- DBX2 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1303818161, COSV100224180; called by muse, mutect2, varscan2
- DCAF6 | c.1390G>A p.E464K (on ENST00000312263 / NM_001349778.1; = p.E484K on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.211); catalogued as COSV100393905; called by muse, mutect2, varscan2
- DDB1 | c.1555C>G p.L519V | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV100074260; called by muse, mutect2, varscan2
- DDX41 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV100286376; called by muse, mutect2, varscan2
- DENND2D | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100718527; called by muse, mutect2, varscan2
- DENND4C | c.3124G>C p.D1042H (on ENST00000434457 / NM_001330640.2; = p.D993H on NM_017925.7) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV100727315, COSV63009499; called by muse, mutect2, varscan2
- DMD | c.5878G>A p.E1960K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as CM115774, COSV100817963, COSV63732656; called by mutect2, varscan2
- DMWD | c.408C>G p.F136L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as COSV99536940; called by mutect2, varscan2
- DNAH11 | c.8957C>G p.S2986C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100177062; called by muse, mutect2, varscan2
- DNAH8 | c.8251G>A p.E2751K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV100543277; called by muse, mutect2, varscan2
- DNAJC8 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99746039; called by muse, mutect2, varscan2
- DPP10 | c.1793G>T p.R598I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV59704114; called by muse, mutect2, varscan2
- DPP10 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100058660; called by muse, mutect2, varscan2
- DSC1 | c.2381G>T p.G794V | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV99937170; called by muse, mutect2, varscan2
- DSC3 | c.1502G>C p.R501T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV100844498; called by muse, mutect2, varscan2
- DST | c.12569C>G p.S4190C (on ENST00000361203 / NM_001374722.1; = p.S1778C on NM_015548.5) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99751014; called by mutect2, varscan2
- DYSF | c.3244G>A p.E1082K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs144599077, CM1514313, COSV50316514; called by muse, mutect2, varscan2
- DZIP3 | c.1775C>G p.S592* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100847623; called by muse, mutect2, varscan2
- EAPP | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV99164211; called by muse, mutect2, varscan2
- ECI1 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100066463; called by muse, mutect2, varscan2
- EFCAB3 | c.126G>C p.K42N | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV100540028; called by muse, mutect2
- EGR1 | c.114G>A p.M38I | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as COSV99525268; called by muse, mutect2, varscan2
- ELF1 | c.1749G>C p.E583D | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99522828; called by muse, mutect2, varscan2
- ELOF1 | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99370580; called by mutect2, varscan2
- EML5 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs1359713699, COSV100715032, COSV61350501; called by muse, mutect2, varscan2
- ENO1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV52303857; called by muse, mutect2, varscan2
- ENPP1 | c.2704C>G p.Q902E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV100719386; called by muse, mutect2, varscan2
- EP300 | c.1712G>A p.W571* | Nonsense Mutation (SNP) | VAF 5/39 reads (13%) | catalogued as COSV54344157, COSV99607339; called by muse, mutect2, varscan2
- EPB41 | c.2209G>A p.V737I (on ENST00000343067 / NM_001166005.2; = p.V495I on NM_004437.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as COSV100548171; called by mutect2, varscan2
- EPHX4 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100952631; called by muse, mutect2, varscan2
- ERC2 | c.510C>G p.I170M | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT tolerated (0.23); PolyPhen benign (0.092); catalogued as COSV99881025; called by muse, mutect2, varscan2
- ERCC6 | c.1735C>A p.H579N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs1241836034, COSV100875680; called by muse, mutect2, varscan2
- ERLIN2 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52422545; called by muse, mutect2, varscan2
- EVA1A | c.321G>C p.L107F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99285297; called by mutect2, varscan2
- EXO1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs567681802, COSV62217034; called by muse, mutect2, varscan2
- EXOC4 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs183280115, COSV54081769, COSV99555488; called by muse, mutect2, varscan2
- FAF2 | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99990222, COSV99990513; called by muse, mutect2, varscan2
- FAM13A | c.525G>C p.L175F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99982834; called by muse, mutect2, varscan2
- FAM189A2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.355); catalogued as COSV57384177, COSV99974714; called by muse, mutect2, varscan2
- FAM234B | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs1209325959, COSV99545359; called by muse, mutect2, varscan2
- FAT1 | c.8548C>T p.Q2850* | Nonsense Mutation (SNP) | VAF 22/37 reads (59%) | catalogued as COSV71672568, COSV71675205; called by muse, mutect2, varscan2
- FBN3 | c.5167G>C p.D1723H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99559763; called by muse, mutect2, varscan2
- FER1L6 | c.1020C>G p.F340L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV101205444; called by muse, mutect2, varscan2
- FIBCD1 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.639); catalogued as rs747110876, COSV99446727; called by muse, varscan2
- FLNA | c.6409G>A p.E2137K (on ENST00000369850 / NM_001110556.2; = p.E2129K on NM_001456.3) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs782142395, COSV61043884; called by muse, mutect2, varscan2
- FLT1 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99147768; called by muse, mutect2, varscan2
- FOXP1 | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV59535489, COSV59557254; called by muse, mutect2, varscan2
- FRK | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374511452; called by muse, varscan2
- FTCD | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs762030809, COSV52424028, COSV99384659; called by muse, mutect2, varscan2
- FXR1 | c.1249G>C p.D417H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV59762038, COSV99976098; called by muse, mutect2, varscan2
- GABRB3 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.826); catalogued as COSV100158191; called by muse, mutect2, varscan2
- GBP2 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | catalogued as COSV100975334; called by muse, mutect2, varscan2
- GBP2 | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV100975335; called by muse, mutect2, varscan2
- GNAI1 | c.117C>T p.L39= | Splice Region (SNP) | VAF 8/13 reads (62%) | catalogued as rs372783127, COSV100650380; called by muse, mutect2, varscan2
- GOLGA1 | c.980C>G p.A327G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs779406119, COSV101001976; called by muse, mutect2, varscan2
- GOT1L1 | c.1149C>G p.I383M | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV56874389, COSV56874788; called by muse, mutect2, varscan2
- GPC5 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as rs770774021, COSV65577357, COSV65577453; called by muse, mutect2, varscan2
- GRIPAP1 | c.315C>A p.S105R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV64553293; called by muse, mutect2, varscan2
- GRP | c.357C>G p.F119L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.675); catalogued as COSV56878968; called by muse, mutect2, varscan2
- GSR | c.1354C>A p.H452N | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.979); catalogued as COSV99645363; called by muse, mutect2, varscan2
- GTPBP8 | c.754C>G p.Q252E | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.374); catalogued as COSV99868200; called by muse, mutect2, varscan2
- H6PD | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs759193407, COSV101072413; called by mutect2, varscan2
- HEATR1 | c.1759G>C p.E587Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV100857421; called by muse, mutect2, varscan2
- HECTD4 | c.10437G>A p.M3479I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as rs370482059; called by muse, mutect2, varscan2
- HECTD4 | c.9862G>A p.D3288N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.998); catalogued as COSV101106707; called by muse, varscan2
- HUNK | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV54233878; called by muse, mutect2, varscan2
- HUWE1 | c.6097+1G>T p.X2033_splice | Splice Site (SNP) | VAF 16/63 reads (25%) | catalogued as COSV99470591; called by muse, mutect2, varscan2
- ICAM2 | c.81C>G p.F27L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99856808; called by mutect2, varscan2
- IL17RA | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV60054820, COSV60055635; called by muse, mutect2
- INO80 | c.1894C>G p.Q632E | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV100731534, COSV100731944; called by muse, mutect2, varscan2
- INTS11 | c.1414G>T p.E472* | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as COSV100027980; called by muse, varscan2
- INTS3 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs1452216843, COSV59676942, COSV59679700; called by muse, mutect2, varscan2
- INTU | c.771G>C p.V257= | Splice Region (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99611431; called by muse, mutect2, varscan2
- IPP | c.176G>T p.S59I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100739378; called by muse, mutect2, varscan2
- IRS4 | c.2878G>A p.V960M | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100929419; called by muse, mutect2, varscan2
- ITCH | c.719C>G p.S240C (on ENST00000262650 / NM_001257137.3; = p.S199C on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52930902; called by muse, mutect2
- JPH2 | c.270C>G p.F90L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as COSV100652513; called by muse, mutect2, varscan2
- KALRN | c.3104G>T p.G1035V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99562110; called by muse, mutect2, varscan2
- KALRN | c.7216C>G p.L2406V (on ENST00000360013 / NM_001024660.4; = p.L709V on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1319671756, COSV52249736, COSV52260777, COSV99361006; called by muse, mutect2, varscan2
- KAT2A | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99863364; called by muse, mutect2, varscan2
- KAT6B | c.3946G>T p.E1316* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99767336; called by muse, mutect2, varscan2
- KCNN2 | c.185C>T p.S62L (on ENST00000264773; = p.S274L on NM_021614.4) | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.055); catalogued as COSV53294805; called by muse, mutect2
- KDM1A | c.1525C>T p.Q509* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as COSV63086744; called by muse, mutect2, varscan2
- KDM5C | c.4627C>G p.L1543V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.093); catalogued as COSV100948758; called by muse, mutect2, varscan2
- KIAA0408 | c.86G>C p.R29T | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100846773; called by muse, mutect2, varscan2
- KIAA1549 | c.5572G>C p.E1858Q | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as COSV99649792; called by muse, mutect2, varscan2
- KIF20A | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV101203081; called by muse, mutect2
- KLHDC4 | c.86C>A p.S29* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99566009; called by muse, mutect2, varscan2
- KLHL2 | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as COSV99899631; called by muse, mutect2, varscan2
- KLHL36 | c.1189G>C p.D397H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV99256456; called by muse, mutect2, varscan2
- KMT5C | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs1279093698, COSV99726049; called by muse, mutect2, varscan2
- KNL1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV100705921; called by muse, mutect2, varscan2
- KRT14 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99390894, COSV99391035; called by muse, mutect2, varscan2
- LAMA4 | c.5011G>A p.E1671K (on ENST00000230538 / NM_001105206.3; = p.E1664K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1562624192, COSV100037591; called by muse, mutect2
- LGR5 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99877464; called by muse, mutect2, varscan2
- LGR6 | c.2217G>A p.M739I (on ENST00000367278 / NM_001017403.1; = p.M687I on NM_021636.3) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV99706015, COSV99707465; called by muse, mutect2, varscan2
- LILRB2 | c.1712G>T p.R571I | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV58743453, COSV58745032; called by muse, mutect2, varscan2
- LIMK2 | c.1804G>C p.E602Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as COSV53223661, COSV99313900; called by muse, mutect2, varscan2
- LIN7A | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV99691710; called by muse, mutect2, varscan2
- LIX1L | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100811059, COSV63417169; called by muse, mutect2, varscan2
- LMTK2 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 17/25 reads (68%) | catalogued as COSV99805997; called by muse, mutect2, varscan2
- LPCAT4 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752945059, COSV59218209; called by muse, mutect2, varscan2
- LPIN2 | c.2415C>G p.F805L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99857945; called by muse, mutect2, varscan2
- LRP1B | c.9215G>C p.R3072T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101252404, COSV67186220, COSV67270909; called by muse, mutect2
- LRPPRC | c.1311C>G p.I437M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV99579853; called by muse, mutect2, varscan2
- LRRK2 | c.2308G>C p.D770H | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as COSV100109194, COSV54154202; called by muse, mutect2
- LTBP2 | c.3475C>T p.Q1159* | Nonsense Mutation (SNP) | VAF 9/12 reads (75%) | catalogued as COSV99999696; called by muse, mutect2, varscan2
- MACC1 | c.788A>G p.H263R | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as COSV60545350; called by muse, mutect2, varscan2
- MAGEB18 | c.83C>T p.T28M | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1416530234, COSV100305291, COSV57465023; called by muse, varscan2
- MAGEC3 | c.1228A>C p.S410R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.296); catalogued as COSV100024829, COSV100026177; called by muse, mutect2, varscan2
- MAP1LC3A | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs1357145981, COSV54159932; called by muse, mutect2, varscan2
- MAP3K14 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100766385; called by muse, mutect2, varscan2
- MAPK11 | c.618C>G p.I206M | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.16); catalogued as rs757173321, COSV99298991; called by muse, mutect2
- MAPK7 | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100218769, COSV55190025; called by muse, mutect2, varscan2
- MARF1 | c.4855G>A p.D1619N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs374000108, COSV100705601; called by muse, mutect2, varscan2
- MATN2 | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.826); catalogued as rs773931953, COSV99645659; called by mutect2, varscan2
- MGA | c.2791C>T p.H931Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0.014); catalogued as COSV99578488; called by muse, mutect2, varscan2
- MLLT11 | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100927363; called by muse, mutect2, varscan2
- MTERF3 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99749546; called by muse, mutect2, varscan2
- MTMR6 | c.356C>G p.S119* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV101110712; called by muse, mutect2
- MUC16 | c.15302C>G p.S5101* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV101198093; called by muse, mutect2, varscan2
- MUC7 | c.977C>A p.S326* | Nonsense Mutation (SNP) | VAF 18/112 reads (16%) | catalogued as COSV100512183; called by muse, mutect2, varscan2
- MXRA8 | c.1191G>C p.Q397H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.431); catalogued as COSV100491827; called by muse, mutect2, varscan2
- MYH7B | c.5056G>A p.E1686K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV99327787; called by mutect2, varscan2
- NAV3 | c.6376G>T p.D2126Y (on ENST00000397909 / NM_001024383.2; = p.D2104Y on NM_014903.6) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99886905; called by muse, mutect2, varscan2
- NCBP1 | c.1215G>A p.M405I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100912531; called by muse, mutect2, varscan2
- NCBP1 | c.2086C>T p.Q696* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100910601; called by muse, mutect2, varscan2
- NCK1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.348); catalogued as COSV56638579; called by muse, mutect2, varscan2
- NCOR1 | c.811G>C p.D271H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99247221; called by muse, mutect2, varscan2
- NDRG3 | c.592G>A p.E198K (on ENST00000349004 / NM_032013.4; = p.E186K on NM_022477.4) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100675311; called by muse, mutect2, varscan2
- NEK7 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV100954364; called by muse, mutect2, varscan2
- NFASC | c.2253G>A p.M751I (on ENST00000339876 / NM_001378329.1; = p.M747I on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as rs1558355104, COSV100362784; called by muse, mutect2, varscan2
- NIPBL | c.4000G>C p.E1334Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99238753; called by muse, mutect2, varscan2
- NKX2-8 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV99352242; called by muse, mutect2
- NR0B1 | c.902A>C p.Q301P | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100973439, COSV66764476; called by muse, mutect2, varscan2
- NSD3 | c.2651C>T p.S884L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.966); catalogued as rs370154301, COSV100395471; called by muse, mutect2, varscan2
- NSMF | c.1202G>A p.G401E (on ENST00000371475 / NM_001130969.3; = p.G399E on NM_015537.4) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99688991, COSV99689529; called by muse, varscan2
- NTN4 | c.1717G>A p.D573N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100643672; called by muse, mutect2, varscan2
- NTSR1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs140186245, COSV65138382; called by muse, mutect2, varscan2
- NUB1 | c.1870G>A p.E624K (on ENST00000568733 / NM_001243351.1; = p.E610K on NM_016118.4) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.045); catalogued as COSV57842100; called by muse, mutect2, varscan2
- NUP155 | c.1401G>C p.L467F (on ENST00000231498 / NM_153485.3; = p.L408F on NM_004298.4) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV51534565, COSV99192206; called by muse, mutect2, varscan2
- NWD1 | c.3469C>G p.L1157V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.632); catalogued as COSV100341736; called by muse, mutect2, varscan2
- NWD1 | c.4153G>C p.E1385Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as COSV100341738; called by mutect2, varscan2
- OBSL1 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755820800, COSV99216199; called by muse, mutect2
- OFD1 | c.3013C>G p.H1005D | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as COSV100366005; called by muse, mutect2, varscan2
- OMD | c.602C>G p.S201C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs776124805, COSV100979015; called by muse, mutect2, varscan2
- OR5K2 | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as COSV101415952; called by muse, mutect2, varscan2
- OR5M8 | c.626C>G p.S209C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV59118021; called by muse, mutect2, varscan2
- OR5T1 | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.182); catalogued as COSV100478713; called by muse, mutect2, varscan2
- OSBPL8 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866552441, COSV53878087, COSV53880397; called by muse, mutect2, varscan2
- P2RX7 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs760498473, COSV99947416; called by muse, mutect2, varscan2
- PARPBP | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs143436739; called by muse, mutect2, varscan2
- PCDHB2 | c.1964C>T p.S655L | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs781921096, COSV50622181; called by muse, mutect2
- PCNX3 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV58420976; called by muse, mutect2, varscan2
- PDHX | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.297); catalogued as COSV99927176; called by muse, mutect2, varscan2
- PEG3 | c.455C>A p.S152* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99687238; called by mutect2, varscan2
- PELO | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV99250663; called by muse, mutect2, varscan2
- PHEX | c.2222G>C p.R741T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.824); catalogued as COSV101039389; called by mutect2, varscan2
- PHLPP1 | c.1855G>A p.D619N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV99407317; called by muse, mutect2, varscan2
- PIGC | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV51129818, COSV99278136; called by muse, mutect2, varscan2
- PIK3C2B | c.1792G>C p.E598Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.502); catalogued as COSV100915980; called by muse, mutect2, varscan2
- PIK3C2B | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.168); catalogued as COSV65804288; called by muse, mutect2, varscan2
- PIK3R4 | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100768202; called by muse, mutect2, varscan2
- PLCH1 | c.1273G>C p.E425Q (on ENST00000340059 / NM_001130960.2; = p.E437Q on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV100395553; called by muse, mutect2, varscan2
- PLD1 | c.2515C>G p.L839V | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.612); catalogued as COSV100577605; called by muse, mutect2
- PLD6 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.003); catalogued as rs756356336, COSV100387554; called by muse, mutect2, varscan2
- PLD6 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.573); catalogued as COSV58634025; called by muse, mutect2, varscan2
- PLEKHH1 | c.3400C>G p.L1134V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as rs774706632, COSV100232663; called by muse, mutect2, varscan2
- PLEKHH2 | c.593C>G p.S198C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.19); catalogued as COSV99174318; called by muse, mutect2, varscan2
- PMCH | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs141964854, COSV59673766; called by muse, varscan2
- PMM2 | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99191105; called by muse, mutect2, varscan2
- PNPLA8 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV99993401; called by muse, mutect2, varscan2
- POLG2 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73376970; called by muse, mutect2, varscan2
- POLR2C | c.756G>T p.L252F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99538198; called by muse, mutect2, varscan2
- POP1 | c.2879C>G p.S960C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100855631; called by muse, mutect2, varscan2
- PPP2R3B | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV101065487; called by muse, mutect2, varscan2
- PRDM15 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54161235; called by muse, mutect2, varscan2
- PRICKLE1 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV100453468; called by muse, mutect2, varscan2
- PRKCB | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100331765, COSV100332253; called by muse, mutect2, varscan2
- PRKDC | c.9491G>T p.W3164L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV100038384; called by muse, mutect2, varscan2
- PRKDC | c.2143G>T p.A715S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100038387; called by muse, mutect2, varscan2
- PROM1 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.3); catalogued as COSV101477038; called by muse, mutect2, varscan2
- PRR27 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.048); catalogued as COSV100748753; called by muse, mutect2, varscan2
- PRUNE2 | c.8488G>A p.E2830K | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99795871; called by muse, mutect2, varscan2
- PRUNE2 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100944216; called by muse, mutect2
- PSMD2 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV100031524; called by muse, mutect2, varscan2
- PTBP2 | c.616C>T p.H206Y (on ENST00000426398 / NM_001300986.2; = p.H198Y on NM_021190.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.259); catalogued as COSV64624397; called by muse, mutect2, varscan2
- PTGDR | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as rs1222242686, COSV60094297; called by muse, mutect2, varscan2
- PTS | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); catalogued as CM121714, COSV99737810; called by muse, mutect2, varscan2
- RBPMS | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as COSV99823618; called by muse, mutect2, varscan2
- RECK | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as rs747098985, COSV100937406; called by muse, mutect2, varscan2
- RETREG3 | c.720G>C p.E240D | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100514882; called by muse, mutect2, varscan2
- RHEX | c.239C>G p.S80C | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV100520011, COSV58981568; called by muse, mutect2, varscan2
- RNFT1 | c.602C>G p.S201* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV99994311; called by muse, mutect2, varscan2
- RPGR | c.2527G>A p.E843K (on ENST00000339363 / NM_001367249.1; = p.E638K on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100139579; called by muse, mutect2
- RPGR | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1044939968, COSV100139581; called by muse, mutect2, varscan2
- RPGRIP1L | c.2927C>G p.S976C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100045819, COSV50903400; called by muse, mutect2, varscan2
- RPIA | c.308G>C p.G103A | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99375890; called by muse, mutect2, varscan2
- RRP1 | c.1305G>C p.R435S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.143); catalogued as COSV101246180; called by muse, mutect2, varscan2
- RTN4 | c.1696G>A p.V566I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs1223634209, COSV100462700; called by muse, mutect2, varscan2
- SCN11A | c.1453G>C p.D485H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.62); catalogued as COSV100180949, COSV56568918; called by muse, mutect2
- SEC24C | c.3083T>C p.L1028P | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.1); catalogued as COSV100226508; called by muse, mutect2, varscan2
- SELL | c.1010C>T p.S337L (on ENST00000650983; = p.S324L on NM_000655.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV99357354; called by muse, mutect2
- SERTAD2 | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV100512096; called by muse, varscan2
- SERTAD4 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100882582; called by muse, mutect2, varscan2
- SF3B1 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV100133800; called by muse, mutect2, varscan2
- SGO1 | c.1370G>A p.R457K (on ENST00000263753 / NM_001012410.5; = p.R188K on NM_138484.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754764910, COSV99768130; called by muse, mutect2, varscan2
- SH2D3C | c.1247C>T p.S416F (on ENST00000314830 / NM_170600.3; = p.S259F on NM_005489.4) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV100136383; called by muse, mutect2, varscan2
- SHISA3 | c.278-1G>C p.X93_splice | Splice Site (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100069777; called by muse, mutect2, varscan2
- SLAMF8 | c.611C>G p.S204C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56989992, COSV99222691, COSV99223042; called by muse, mutect2, varscan2
- SLC26A4 | c.1882G>C p.D628H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as COSV99706540; called by muse, mutect2, varscan2
- SLC38A4 | c.955G>C p.D319H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.89); catalogued as COSV99872449; called by muse, mutect2, varscan2
- SLITRK1 | c.2062G>C p.D688H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV100999779; called by muse, mutect2, varscan2
- SMARCA5 | c.2651C>T p.S884L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV99303441; called by muse, mutect2, varscan2
- SMC5 | c.2095G>C p.E699Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100746959; called by muse, mutect2, varscan2
- SORCS3 | c.3465C>G p.I1155M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100864516; called by mutect2, varscan2
- SPAG17 | c.2634C>G p.I878M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100307913; called by muse, mutect2, varscan2
- SPATA18 | c.1325G>C p.G442A | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.391); catalogued as COSV54645040, COSV99730004; called by muse, mutect2
- SPHKAP | c.2749C>T p.Q917* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100763686; called by muse, mutect2, varscan2
- SRGAP1 | c.1320C>A p.F440L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.07); catalogued as COSV100754205; called by muse, mutect2, varscan2
- STAG3 | c.3569C>G p.S1190* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100116610; called by mutect2, varscan2
- STAT6 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.079); catalogued as COSV100272514; called by muse, mutect2, varscan2
- SUCO | c.532G>C p.D178H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.109); catalogued as COSV99742014; called by muse, mutect2, varscan2
- SURF2 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs1199435168, COSV100914286, COSV100914294; called by muse, mutect2, varscan2
- SUSD2 | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV99572687; called by muse, mutect2, varscan2
- TAB3 | c.865C>G p.Q289E | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); catalogued as COSV55840266; called by muse, mutect2, varscan2
- TAF1 | c.2926C>T p.R976C (on ENST00000373790 / NM_138923.4; = p.R997C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52108288; called by mutect2, varscan2
- TAF9 | c.553C>G p.Q185E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.749); catalogued as COSV99472600; called by muse, mutect2, varscan2
- TBL3 | c.1100C>A p.S367* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100224686; called by muse, mutect2, varscan2
- TCERG1 | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV99694380; called by muse, mutect2, varscan2
- TCHH | c.2591G>C p.R864P | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV64273147, COSV64274723; called by mutect2, varscan2
- TG | c.4841G>A p.S1614N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.094); catalogued as COSV55093026; called by muse, mutect2, varscan2
- TGM6 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.106); catalogued as COSV52482088, COSV99171679; called by muse, mutect2, varscan2
- TGS1 | c.886C>G p.P296A | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as COSV52698114, COSV99485049; called by muse, mutect2
- THADA | c.4629C>G p.I1543M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs1452720331, COSV100367930; called by muse, mutect2, varscan2
- THADA | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.628); catalogued as COSV100367932, COSV100369057; called by muse, mutect2, varscan2
- TIAM2 | c.1309C>G p.Q437E | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.085); catalogued as COSV100017970; called by muse, mutect2, varscan2
- TIGD3 | c.1060C>T p.Q354* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as rs1378998208, COSV99361330; called by muse, mutect2
- TLN2 | c.140C>G p.S47C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV100167970; called by muse, mutect2, varscan2
- TM9SF2 | c.1097C>T p.S366L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV100899650; called by muse, mutect2, varscan2
- TMEM30A | c.14A>G p.Y5C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs1002060565, COSV100034702; called by muse, mutect2, varscan2
- TMOD1 | c.619-1G>A p.X207_splice | Splice Site (SNP) | VAF 9/23 reads (39%) | catalogued as COSV99403708; called by muse, mutect2, varscan2
- TNNT1 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1214224674, COSV52571493, COSV99402677; called by muse, mutect2, varscan2
- TP53BP2 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100636501, COSV100636839; called by mutect2, varscan2
- TPM3 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99666008; called by muse, mutect2, varscan2
- TRAF3 | c.1291G>C p.E431Q | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV100693434; called by muse, mutect2, varscan2
- TRIM60 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100593916, COSV100593956; called by muse, mutect2, varscan2
- TRIM7 | c.944C>G p.S315C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV51246993, COSV99219988; called by muse, mutect2, varscan2
- TRPM8 | c.2592G>A p.L864= | Splice Region (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100223581; called by muse, mutect2, varscan2
- TSGA10 | c.1239G>A p.M413I | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100747432; called by muse, mutect2, varscan2
- TTN | c.25042G>C p.E8348Q (on ENST00000591111; = p.E7421Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/51 reads (10%) | PolyPhen benign (0.318); catalogued as COSV100593988; called by muse, mutect2
- TUBD1 | c.1076-1G>A p.X359_splice | Splice Site (SNP) | VAF 3/36 reads (8%) | catalogued as COSV100359949; called by muse, mutect2
- TYRO3 | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99777173; called by muse, mutect2, varscan2
- UAP1 | c.1275G>C p.L425F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99617381; called by muse, mutect2, varscan2
- UPF1 | c.1708C>G p.L570V (on ENST00000599848 / NM_001297549.2; = p.L559V on NM_002911.4) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99438795; called by muse, mutect2, varscan2
- UPF2 | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100706922; called by muse, mutect2, varscan2
- USH2A | c.7114G>A p.D2372N | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs766071413, COSV100228912; called by muse, mutect2, varscan2
- USP49 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51896676; called by muse, mutect2, varscan2
- USP9X | c.643C>G p.R215G | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV100198470; called by muse, mutect2, varscan2
- UTP20 | c.7200G>C p.E2400D | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV99880768; called by muse, mutect2, varscan2
- VARS1 | c.3718G>A p.E1240K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV100791779; called by muse, mutect2, varscan2
- WBP4 | c.576G>T p.E192D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV101069213; called by muse, mutect2, varscan2
- WBP4 | c.1052G>T p.G351V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101069215, COSV65274744; called by muse, mutect2, varscan2
- WDR24 | c.2171C>T p.S724F (on ENST00000248142; = p.S594F on NM_032259.4) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99555369; called by muse, mutect2
- WRAP73 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.021); catalogued as COSV99573103; called by muse, mutect2, varscan2
- ZC3H12D | c.27C>G p.F9L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as COSV101116790, COSV66324220; called by muse, mutect2, varscan2
- ZC3H13 | c.2390G>A p.R797Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.968); catalogued as rs183796238, COSV99667443; called by muse, mutect2, varscan2
- ZDHHC12 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs371747221, COSV99403271; called by muse, mutect2, varscan2
- ZFAT | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as COSV100914226; called by muse, mutect2, varscan2
- ZFHX4 | c.8235G>C p.E2745D | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.908); catalogued as COSV99256042; called by muse, mutect2, varscan2
- ZGRF1 | c.6276G>C p.K2092N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as COSV71392882; called by muse, mutect2, varscan2
- ZNF175 | c.1816C>G p.Q606E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs764661866, COSV99219266; called by muse, mutect2, varscan2
- ZNF221 | c.737G>A p.R246K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV99240549; called by muse, mutect2, varscan2
- ZNF358 | c.1411C>G p.L471V | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs149848212; called by muse, mutect2, varscan2
- ZNF433 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100794923; called by muse, mutect2, varscan2
- ZNF560 | c.776C>G p.S259C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV56866754; called by muse, mutect2, varscan2
- ZNF569 | c.1933C>G p.Q645E | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV100386328; called by muse, mutect2, varscan2
- ZNF609 | c.3589G>C p.E1197Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV100440374; called by muse, mutect2, varscan2
- ZNF611 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV100160017; called by muse, mutect2, varscan2
- ZNF644 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV61346271; called by muse, mutect2
- ZNF761 | c.1205G>A p.R402K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.335); catalogued as COSV100483256; called by muse, mutect2
- ZNF813 | c.1498T>A p.C500S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101124683; called by muse, varscan2
- ZSWIM3 | c.314C>G p.S105C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV99666102; called by mutect2, varscan2
- ZXDA | c.2005C>G p.Q669E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.416); catalogued as rs1049355923, COSV100699355; called by muse, mutect2, varscan2
- ZZZ3 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.293); catalogued as COSV100890204; called by mutect2, varscan2
- ACE | c.287_296del p.A96Gfs*46 | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | called by mutect2, pindel, varscan2
- FYCO1 | c.4294_4302del p.I1432_G1434del | In Frame Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- GRIN2C | c.498del p.V167Sfs*25 | Frame Shift Del (DEL) | VAF 6/11 reads (55%) | called by mutect2, varscan2
- IGLV2-18 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- REC8 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STAT6 | c.1392del p.T465Pfs*73 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.99); called by muse, mutect2
- SUPT20HL1 | c.2104C>G p.Q702E | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- TTN | c.12406G>C p.E4136Q (on ENST00000591111; = p.E4090Q on NM_003319.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- ZNF208 | c.2059C>T p.H687Y | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2
- AGO2 | c.1620G>A p.L540= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs751224339, COSV99595234; called by mutect2, varscan2
- AHNAK | c.11646G>A p.L3882= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV99945536; called by muse, mutect2, varscan2
- ALDH1L1 | c.1350C>T p.I450= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs768520796, COSV99856496; called by muse, mutect2
- AMHR2 | c.381G>A p.G127= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99142995; called by muse, mutect2, varscan2
- AQP2 | c.747C>T p.R249= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs1395816664, COSV52230425; called by muse, mutect2, varscan2
- ATXN2L | c.798G>A p.V266= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV57365207; called by muse, mutect2, varscan2
- C11orf16 | c.105C>G p.L35= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100393603; called by muse, mutect2, varscan2
- C1orf94 | c.858G>A p.L286= (on ENST00000488417 / NM_001134734.2; = p.L96= on NM_032884.5) | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100974668, COSV64915677; called by muse, mutect2, varscan2
- C20orf194 | c.1878G>T p.L626= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV99330279; called by muse, mutect2, varscan2
- CACNA1H | c.2295G>A p.Q765= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100670778; called by muse, mutect2, varscan2
- CAPN9 | c.1008C>T p.L336= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs1302938529, COSV99679912; called by muse, mutect2, varscan2
- CDC25A | c.1574G>A p.*525= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as COSV100207305; called by muse, mutect2, varscan2
- CIAO1 | c.429C>T p.V143= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99302453; called by muse, mutect2, varscan2
- CIITA | c.219C>T p.I73= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100161353; called by muse, mutect2, varscan2
- CIZ1 | c.666G>C p.R222= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV99476624; called by muse, mutect2, varscan2
- CNTNAP1 | c.3333C>T p.L1111= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV99226114; called by muse, mutect2, varscan2
- COL4A6 | c.4179C>T p.L1393= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100563331; called by muse, mutect2, varscan2
- DAGLA | c.1476C>T p.L492= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV99943956; called by muse, mutect2, varscan2
- DAND5 | c.396C>G p.L132= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100397187; called by muse, mutect2, varscan2
- DCPS | c.606C>T p.L202= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99703332; called by muse, mutect2
- DHX36 | c.171G>A p.L57= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV57677533; called by muse, mutect2, varscan2
- DMXL1 | c.8556G>C p.L2852= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV100223267; called by muse, mutect2, varscan2
- DOP1A | c.378C>T p.L126= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs772292377, COSV99380934; called by muse, mutect2, varscan2
- DRD2 | c.246C>G p.L82= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100669289, COSV60762100; called by muse, mutect2, varscan2
- EGLN3 | c.141C>G p.V47= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99164285; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1797C>T p.L599= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs757920159, COSV100348864; called by muse, mutect2, varscan2
- EXOC3L1 | c.580C>T p.L194= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99333414; called by muse, mutect2, varscan2
- FAM83A | c.525C>T p.F175= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99413988; called by muse, mutect2
- FEM1B | c.813G>A p.K271= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as COSV100183547, COSV60988618; called by muse, mutect2
- FNDC1 | c.3684C>T p.I1228= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs758602860, COSV51929804, COSV99794880; called by muse, mutect2, varscan2
- FSD1 | c.987C>G p.P329= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99696581; called by muse, mutect2, varscan2
- FXYD5 | c.45G>C p.L15= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99544715; called by mutect2, varscan2
- GABBR2 | c.1425G>A p.R475= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV99409176; called by muse, mutect2, varscan2
- GEMIN5 | c.273G>T p.V91= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99501520; called by muse, mutect2, varscan2
- GMIP | c.1434G>T p.L478= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs1486106072, COSV99179075; called by muse, mutect2, varscan2
- GTF3C5 | c.90G>T p.P30= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV100565246; called by muse, mutect2, varscan2
- HECTD4 | c.9927G>A p.K3309= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs1420127588, COSV101106705; called by muse, varscan2
- HSD17B1 | c.456C>T p.F152= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs1352911781, COSV99864635; called by muse, mutect2, varscan2
- IGHV1-24 | c.261C>T p.V87= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs1555470067; called by muse, mutect2, varscan2
- IL22RA1 | c.402G>C p.S134= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99582780; called by muse, mutect2
- INTS11 | c.1254G>A p.K418= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1156290068, COSV100027983; called by muse, varscan2
- INTS11 | c.954G>C p.P318= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV100027986; called by muse, mutect2, varscan2
- ITGAE | c.876C>T p.I292= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs1340535247, COSV99560357; called by muse, mutect2, varscan2
- KBTBD12 | c.1053G>A p.K351= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100675355; called by muse, mutect2, varscan2
- KCNA1 | c.267C>T p.F89= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs371963908; called by muse, mutect2, varscan2
- KIAA0753 | c.186G>A p.L62= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100810527; called by muse, mutect2, varscan2
- KIF27 | c.2215C>T p.L739= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV99926645; called by muse, mutect2, varscan2
- KIT | c.2556C>G p.V852= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV99853263; called by muse, mutect2
- KRT14 | c.1161C>T p.L387= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs748972921, COSV51421762, COSV99390892; called by muse, mutect2, varscan2
- LEXM | c.783G>A p.L261= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100827466; called by muse, mutect2, varscan2
- LLGL1 | c.1440G>A p.Q480= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100375062; called by muse, mutect2, varscan2
- LRGUK | c.150G>C p.T50= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99603715, COSV99604561; called by muse, mutect2, varscan2
- LRRC37A3 | c.4803C>G p.L1601= | Silent (SNP) | VAF 16/161 reads (10%) | catalogued as COSV100140825, COSV58537081; called by muse, mutect2
- LRRN3 | c.978C>T p.H326= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100067743; called by mutect2, varscan2
- MAGOH | c.330C>T p.V110= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV101012327, COSV65161175; called by muse, mutect2, varscan2
- MAP3K12 | c.246G>A p.Q82= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV57235857, COSV99913427; called by muse, mutect2
- MAP3K4 | c.1977G>A p.L659= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100815026; called by muse, mutect2, varscan2
- MAP4K4 | c.222G>A p.K74= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV100153425, COSV56336064; called by muse, mutect2, varscan2
- MCM6 | c.993G>A p.V331= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99918740; called by mutect2, varscan2
- MRC1 | c.330C>T p.I110= | Silent (SNP) | VAF 63/136 reads (46%) | catalogued as COSV58888583; called by muse, mutect2, varscan2
- MUC3A | c.9114C>G p.L3038= | Silent (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- MUC5B | c.13782G>A p.P4594= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs752326374; called by muse, mutect2, varscan2
- MYF5 | c.9G>C p.V3= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99953108; called by muse, mutect2, varscan2
- MYH7B | c.2109C>G p.L703= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99482261; called by muse, mutect2, varscan2
- MYH8 | c.5802C>T p.I1934= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV101238080, COSV67959650; called by muse, mutect2, varscan2
- NFATC4 | c.1326C>G p.V442= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV99144244; called by muse, mutect2, varscan2
- NLRP4 | c.1125C>T p.F375= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs373243158, COSV56710515; called by muse, mutect2, varscan2
- NMRAL1 | c.540A>T p.T180= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99361628; called by mutect2, varscan2
- OPN1LW | c.405G>C p.L135= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs1557157474, COSV100886848; called by muse, mutect2, varscan2
- PCDHA1 | c.1767T>C p.H589= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV100974260; called by muse, mutect2, varscan2
- POFUT2 | c.609G>A p.A203= | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as rs759590287, COSV100499112, COSV57961745; called by muse, mutect2, varscan2
- POPDC2 | c.171G>C p.L57= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV99950821; called by muse, mutect2, varscan2
- POU2F1 | c.1866G>A p.L622= (on ENST00000541643 / NM_001365848.1; = p.L645= on NM_002697.4) | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99610428; called by muse, mutect2, varscan2
- POU5F1 | c.216G>A p.G72= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99462719; called by mutect2, varscan2
- PPEF1 | c.51G>A p.L17= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100583548; called by muse, mutect2, varscan2
- PRDM1 | c.303G>C p.V101= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100958541; called by muse, mutect2, varscan2
- PRDM14 | c.274C>T p.L92= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV99399864; called by muse, mutect2, varscan2
- PREPL | c.36G>A p.L12= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99575915; called by muse, mutect2, varscan2
- PROM1 | c.1662C>T p.L554= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs756279080, COSV101477037; called by muse, mutect2, varscan2
- PTGES2 | c.864C>T p.L288= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1235138567, COSV99476234; called by muse, mutect2, varscan2
- RAB6A | c.99C>T p.F33= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs142720463; called by muse, mutect2, varscan2
- RAD51C | c.207C>G p.L69= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV53617603, COSV99541375; called by muse, mutect2, varscan2
- RANGRF | c.114C>T p.F38= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV99873665; called by muse, mutect2, varscan2
- REG1B | c.351C>T p.S117= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100521265; called by muse, mutect2, varscan2
- RFT1 | c.789G>A p.V263= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99965323; called by muse, mutect2, varscan2
- RGN | c.522C>T p.S174= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs781977550, COSV100282387; called by muse, mutect2, varscan2
- RHPN1 | c.1725G>C p.L575= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV100000440; called by muse, mutect2, varscan2
- RTTN | c.2214C>T p.L738= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV55342084, COSV99733912; called by muse, mutect2, varscan2
- RUFY3 | c.726C>T p.L242= | Silent (SNP) | VAF 47/70 reads (67%) | catalogued as COSV99886826; called by muse, mutect2, varscan2
- S100A8 | c.36C>T p.I12= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV64198301; called by muse, mutect2, varscan2
- SDK2 | c.5979C>G p.L1993= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs752640012, COSV101166761; called by muse, mutect2, varscan2
- SEMA4F | c.1854G>A p.V618= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100335722; called by muse, mutect2, varscan2
- SERINC5 | c.63C>T p.L21= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV101549047; called by muse, mutect2, varscan2
- SERPINB9 | c.396C>T p.I132= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV101046461; called by muse, mutect2
- SERPINF1 | c.1224C>T p.F408= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV99628674; called by muse, mutect2, varscan2
- SERTAD2 | c.246G>C p.L82= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100512098; called by muse, varscan2
- SLC19A1 | c.171G>A p.K57= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs765827796, COSV100229106; called by muse, mutect2, varscan2
- SLC1A7 | c.1083C>T p.I361= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs761706271, COSV65198455; called by muse, mutect2, varscan2
- SLC32A1 | c.945C>T p.F315= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99461769; called by muse, mutect2, varscan2
- SLC4A5 | c.1965G>A p.K655= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100697391; called by muse, mutect2
- SLC9C2 | c.2425C>A p.R809= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100876564, COSV100877048; called by muse, mutect2, varscan2
- SLCO1A2 | c.699C>T p.I233= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs201550748, COSV100261328; called by muse, mutect2, varscan2
- SNRNP200 | c.351C>G p.L117= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs533123827, COSV100107090; ClinVar: likely benign; called by muse, mutect2, varscan2
- SOWAHB | c.2052G>C p.G684= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100530588; called by muse, mutect2
- SPOCD1 | c.1464C>T p.I488= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV99929422; called by muse, mutect2, varscan2
- SRCIN1 | c.3435G>A p.A1145= (on ENST00000621492; = p.A1111= on NM_025248.3) | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs778228503; called by muse, mutect2, varscan2
- SRRM2 | c.1833G>A p.R611= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as COSV57074812, COSV57077309; called by muse, mutect2, varscan2
- STYXL1 | c.129C>T p.D43= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs782769455, COSV99951239; called by muse, mutect2, varscan2
- SYNGAP1 | c.315G>A p.S105= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV53378806; called by muse, mutect2, varscan2
- SYTL1 | c.102C>T p.L34= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100539114; called by muse, mutect2, varscan2
- TCAF2 | c.1641C>T p.T547= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as rs1273620714, COSV100633516; called by muse, mutect2, varscan2
- TENM1 | c.2007C>T p.H669= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs768785681, COSV100949008; called by muse, mutect2, varscan2
- TENT4A | c.1341G>A p.L447= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100048606; called by muse, mutect2, varscan2
- TGFA | c.411C>T p.I137= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV99772574; called by muse, mutect2, varscan2
- TLE3 | c.357G>A p.L119= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100450046; called by muse, mutect2, varscan2
- TMBIM1 | c.129G>A p.P43= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs564213152, COSV99297768; called by muse, mutect2, varscan2
- TMEM139 | c.175C>T p.L59= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100130843; called by muse, mutect2
- TMEM219 | c.255C>T p.V85= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs369756545; called by muse, mutect2, varscan2
- TRIM7 | c.780C>T p.I260= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99219991; called by muse, mutect2
- TRPM2 | c.1764C>A p.L588= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV100308193, COSV100308513; called by muse, mutect2, varscan2
- UBA1 | c.1923C>T p.I641= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100255394; called by muse, mutect2, varscan2
- UNC79 | c.2517C>T p.F839= (on ENST00000393151 / NM_001346218.2; = p.F662= on NM_020818.5) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99825753; called by muse, mutect2, varscan2
- USP13 | c.153C>T p.F51= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99830725; called by mutect2, varscan2
- UXT | c.147C>T p.Y49= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as COSV100243779; called by muse, mutect2, varscan2
- VPS13B | c.8907G>A p.V2969= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100660851; called by muse, mutect2, varscan2
- VPS26A | c.246G>A p.K82= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99697463; called by muse, mutect2, varscan2
- VWA2 | c.1413A>G p.R471= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100073293; called by muse, mutect2, varscan2
- WARS2 | c.228C>G p.L76= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV52483077, COSV99345909; called by muse, mutect2, varscan2
- ZHX2 | c.1929G>C p.L643= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV58712920; called by muse, mutect2, varscan2
- ZKSCAN3 | c.147C>T p.F49= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99356761; called by muse, mutect2, varscan2
- ZNF16 | c.1428C>G p.L476= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99429409; called by muse, mutect2, varscan2
- ZNF330 | c.714G>A p.Q238= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as COSV99522419; called by muse, mutect2, varscan2
- ZNF414 | c.165G>A p.V55= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs1197128377, COSV99726434; called by muse, mutect2, varscan2
- ZNHIT6 | c.756G>A p.L252= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100995491; called by muse, mutect2, varscan2
- C9orf106 | n.327G>A | RNA (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- CCSER1 | c.2094+23187A>C | Intron (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*3791G>C | 3'UTR (SNP) | VAF 8/18 reads (44%) | catalogued as COSV57072395; called by muse, mutect2, varscan2
- DHRS4 | c.*2G>T | 3'UTR (SNP) | VAF 15/41 reads (37%) | catalogued as rs766915550, COSV100365746; called by muse, mutect2, varscan2
- EXOC3 | chr5:442797 G>A | 5'Flank (SNP) | VAF 7/45 reads (16%) | catalogued as rs1285174798; called by muse, mutect2, varscan2
- FRMPD2B | n.599C>A | RNA (SNP) | VAF 15/57 reads (26%) | called by mutect2, varscan2
- HLA-F | c.1036+166C>T | Intron (SNP) | VAF 4/23 reads (17%) | called by mutect2, varscan2
- LIMK2 | c.1773-1163G>A | Intron (SNP) | VAF 16/33 reads (48%) | catalogued as rs779094138, COSV99313897; called by muse, mutect2, varscan2
- MDS2 | n.623G>C | RNA (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- MIB1 | c.1829+6053C>T | Intron (SNP) | VAF 17/31 reads (55%) | catalogued as COSV99838346; called by muse, mutect2, varscan2
- MIR1270 | chr19:20397358 C>G | 3'Flank (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- MRPL39 | c.969+1067C>G | Intron (SNP) | VAF 4/11 reads (36%) | catalogued as rs778553343, COSV100220836; called by mutect2, varscan2
- MUTYH | c.36+300C>G | Intron (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100517051, COSV59150709; called by muse, mutect2
- SNORD116-28 | n.85G>C | RNA (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- TPM3 | c.642+571G>A | Intron (SNP) | VAF 14/49 reads (29%) | catalogued as COSV99666006; called by muse, mutect2, varscan2
- UBTFL2 | n.645C>G | RNA (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2, varscan2
- ZNF99 | c.*245T>C | 3'UTR (SNP) | VAF 15/38 reads (39%) | catalogued as COSV101233700; called by muse, mutect2, varscan2
